Somatic mutation profile of tumor specimen TCGA-SI-AA8B-01A (aliquot TCGA-SI-AA8B-01A-11D-A387-09) from TCGA case TCGA-SI-AA8B, project TCGA-SARC (Sarcoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Undifferentiated sarcoma; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of lower limb and hip; Age at diagnosis: 80.3 years (29,315 days).
Specimen TCGA-SI-AA8B-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 546eebab-23e6-4960-b638-779cc1c1a6e4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-SI-AA8B-10A (Blood Derived Normal), aliquot TCGA-SI-AA8B-10A-01D-A38A-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cca418d0-690e-4a59-8438-07eb6ac028bc

The open-access MAF lists 45 somatic variants for this specimen: 35 protein-altering or splice-affecting, 10 silent.
By variant classification: Missense Mutation 28, Silent 10, Nonsense Mutation 5, Frame Shift Del 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALDH1L1 | c.257G>T p.C86F | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV99856412, COSV99857689; called by muse, mutect2
- AMOT | c.2591C>T p.T864I (on ENST00000371959 / NM_001113490.1; = p.T455I on NM_133265.3) | Missense Mutation (SNP) | VAF 11/99 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV100495689, COSV59060468; called by muse, mutect2, varscan2
- ATRX | c.2062A>T p.K688* | Nonsense Mutation (SNP) | VAF 23/47 reads (49%) | catalogued as COSV100971661; called by muse, mutect2, varscan2
- CAPN7 | c.196G>A p.A66T | Missense Mutation (SNP) | VAF 28/68 reads (41%) | SIFT tolerated (0.56); PolyPhen benign (0.012); catalogued as COSV99513111; called by muse, mutect2, varscan2
- CCDC9B | c.599G>A p.R200Q | Missense Mutation (SNP) | VAF 41/134 reads (31%) | SIFT tolerated (0.39); PolyPhen benign (0.009); catalogued as rs755954950, COSV66875355; called by muse, mutect2, varscan2
- ETV1 | c.623G>T p.R208L | Missense Mutation (SNP) | VAF 41/216 reads (19%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.796); catalogued as COSV54146379, COSV99624824; called by muse, mutect2, varscan2
- F7 | c.185A>G p.N62S | Missense Mutation (SNP) | VAF 29/308 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.536); catalogued as rs1275033181, COSV100661128; called by muse, mutect2
- F8 | c.6406G>A p.G2136R | Missense Mutation (SNP) | VAF 22/122 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM096963, COSV100812134; called by muse, mutect2, varscan2
- GRM8 | c.1958T>A p.V653D | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.633); catalogued as COSV100286883; called by muse, mutect2, varscan2
- KATNAL1 | c.395C>T p.A132V | Missense Mutation (SNP) | VAF 59/109 reads (54%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs769731518, COSV101017272; called by muse, mutect2, varscan2
- MEFV | c.1060C>T p.R354W | Missense Mutation (SNP) | VAF 49/167 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.723); catalogued as rs104895116, CM035568, COSV54824683; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MLIP | c.130C>A p.P44T | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV99230864; called by muse, mutect2, varscan2
- OR2T1 | c.522C>A p.N174K | Missense Mutation (SNP) | VAF 37/42 reads (88%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.904); catalogued as COSV63543050; called by muse, mutect2, varscan2
- OR52M1 | c.186C>G p.Y62* | Nonsense Mutation (SNP) | VAF 19/107 reads (18%) | catalogued as rs776713053, COSV100798627, COSV64171454; called by muse, mutect2, varscan2
- PNPLA6 | c.2822T>A p.F941Y (on ENST00000414982 / NM_001166111.2; = p.F893Y on NM_006702.5) | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV99654717; called by muse, mutect2, varscan2
- POF1B | c.430C>G p.P144A | Missense Mutation (SNP) | VAF 48/97 reads (49%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.005); catalogued as COSV99427672; called by muse, mutect2, varscan2
- PSMF1 | c.371A>G p.Y124C | Missense Mutation (SNP) | VAF 23/39 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs371369250; called by muse, mutect2, varscan2
- RASSF8 | c.748A>T p.K250* | Nonsense Mutation (SNP) | VAF 10/36 reads (28%) | catalogued as COSV99281026; called by muse, mutect2, varscan2
- SBNO1 | c.1631A>G p.K544R (on ENST00000420886; = p.K543R on NM_018183.5) | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated (0.94); PolyPhen benign (0.127); catalogued as COSV99929902; called by muse, mutect2, varscan2
- SGPL1 | c.584T>C p.L195P | Missense Mutation (SNP) | VAF 42/103 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100167369; called by muse, mutect2, varscan2
- SKAP1 | c.16C>T p.L6F | Missense Mutation (SNP) | VAF 26/155 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.655); catalogued as COSV100412454; called by muse, mutect2, varscan2
- SLAIN2 | c.661C>T p.R221* | Nonsense Mutation (SNP) | VAF 8/69 reads (12%) | catalogued as COSV99971950; called by muse, mutect2
- SOX3 | c.463C>T p.R155C | Missense Mutation (SNP) | VAF 33/218 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65168713; called by muse, mutect2, varscan2
- SPIB | c.30C>A p.D10E | Missense Mutation (SNP) | VAF 66/186 reads (35%) | SIFT tolerated (0.64); PolyPhen probably damaging (0.964); catalogued as rs778756578, COSV99570206; called by muse, mutect2, varscan2
- TAF1 | c.1228C>T p.R410C (on ENST00000373790 / NM_138923.4; = p.R431C on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/79 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.582); catalogued as COSV52117281; called by muse, mutect2, varscan2
- TAOK1 | c.865G>A p.V289M | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.764); catalogued as rs1472553618, COSV55591677; called by muse, mutect2, varscan2
- TMEM187 | c.247C>T p.R83C | Missense Mutation (SNP) | VAF 7/98 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.012); catalogued as rs782069564, COSV100890211; called by muse, mutect2
- TPH2 | c.1427C>T p.T476I | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as rs769557162, COSV100422469; called by muse, mutect2, varscan2
- TTLL9 | c.829C>T p.R277C | Missense Mutation (SNP) | VAF 30/71 reads (42%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.809); catalogued as rs369485862; called by muse, mutect2, varscan2
- TUBGCP2 | c.2528A>G p.Y843C | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.571); catalogued as COSV99428454; called by muse, mutect2, varscan2
- ZBED9 | c.3557T>A p.L1186* | Nonsense Mutation (SNP) | VAF 23/72 reads (32%) | catalogued as COSV101509435; called by muse, mutect2, varscan2
- ZNF536 | c.1093C>A p.R365S | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100835428, COSV100836169; called by muse, mutect2, varscan2
- CDAN1 | c.1096del p.C366Vfs*24 | Frame Shift Del (DEL) | VAF 53/125 reads (42%) | called by mutect2, pindel, varscan2
- NACC2 | c.712C>G p.Q238E | Missense Mutation (SNP) | VAF 22/218 reads (10%) | SIFT tolerated (0.92); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- OR8K1 | c.39del p.K14Rfs*2 | Frame Shift Del (DEL) | VAF 6/63 reads (10%) | called by mutect2, pindel, varscan2
- BAP1 | c.1128C>T p.D376= | Silent (SNP) | VAF 15/63 reads (24%) | catalogued as rs756683094, COSV99964630; called by muse, mutect2, varscan2
- CACNA1A | c.2397C>T p.N799= | Silent (SNP) | VAF 67/160 reads (42%) | catalogued as rs1016423592, COSV64192411; called by muse, mutect2, varscan2
- CACNA2D3 | c.3054C>G p.L1018= | Silent (SNP) | VAF 57/124 reads (46%) | catalogued as COSV99878159; called by muse, mutect2, varscan2
- GPR119 | c.930C>A p.A310= | Silent (SNP) | VAF 13/88 reads (15%) | catalogued as COSV99358743; called by muse, mutect2, varscan2
- INAVA | c.1332G>A p.P444= | Silent (SNP) | VAF 24/79 reads (30%) | catalogued as rs1456644448, COSV100950164; called by muse, mutect2, varscan2
- MYMK | c.360C>T p.G120= | Silent (SNP) | VAF 21/66 reads (32%) | catalogued as COSV101301187; called by muse, mutect2, varscan2
- NSD2 | c.795G>A p.Q265= | Silent (SNP) | VAF 58/107 reads (54%) | catalogued as COSV100374085; called by muse, mutect2, varscan2
- OPRK1 | c.9C>T p.S3= | Silent (SNP) | VAF 24/48 reads (50%) | catalogued as COSV99654502; called by muse, mutect2, varscan2
- PIWIL2 | c.333G>A p.K111= | Silent (SNP) | VAF 18/95 reads (19%) | catalogued as COSV100769601; called by muse, mutect2, varscan2
- SYNPO2 | c.3603C>G p.V1201= | Silent (SNP) | VAF 11/74 reads (15%) | catalogued as COSV100206592; called by muse, mutect2, varscan2
